Somatic mutation profile of tumor specimen 0DEFJT from CCDI case PBBPWT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,448 days).
Specimen 0DEFJT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52d7f06f-e516-4b2a-b128-043177df5fc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEFHP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28fde9b9-146d-4c45-8048-a3a7d04da1da

The open-access MAF lists 27 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 5, 3'UTR 5, Silent 4, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH5A1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 66/590 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370988709; called by muse, varscan2
- LEPR | c.3236A>C p.Y1079S | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD1515423; called by muse, mutect2, varscan2
- TFAP4 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 39/423 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV52596945; called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CHRDL2 | c.1235C>G p.A412G (on ENST00000376332 / NM_001304415.1; = p.S430R on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ETS1 | c.827G>C p.S276T | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.073); called by muse, mutect2
- HSD17B3 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 44/1332 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- MAP3K9 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 74/543 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MUC22 | c.1544C>A p.T515N | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT tolerated (0.14); called by mutect2, varscan2
- RAD21 | c.964A>G p.R322G | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 29/528 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- DDB1 | c.144G>C p.G48= | Silent (SNP) | VAF 84/548 reads (15%) | called by muse, mutect2, varscan2
- PRRC2A | c.4776A>G p.P1592= | Silent (SNP) | VAF 20/554 reads (4%) | called by muse, mutect2
- PSAPL1 | c.219C>T p.A73= | Silent (SNP) | VAF 41/283 reads (14%) | catalogued as rs772898477; called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 28/522 reads (5%) | catalogued as rs1267156464; called by muse, mutect2
- AHSP | c.*19C>G | 3'UTR (SNP) | VAF 18/452 reads (4%) | catalogued as rs1410737057; called by muse, mutect2
- ANKRD28 | c.2784-37G>A | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, varscan2
- ARFGEF2 | c.3222-64A>G | Intron (SNP) | VAF 18/271 reads (7%) | called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 26/193 reads (13%) | called by muse, varscan2
- FAHD2A | c.*33G>C | 3'UTR (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- GPR37 | c.*77T>C | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 21/191 reads (11%) | catalogued as rs1415560984; called by mutect2, varscan2
- MDM4 | c.343+72A>G | Intron (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- NEDD4L | c.2257-78G>T | Intron (SNP) | VAF 6/84 reads (7%) | called by mutect2, varscan2
- OR1B1 | c.-37G>A | 5'UTR (SNP) | VAF 82/365 reads (22%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45226132 C>G | 3'Flank (SNP) | VAF 49/287 reads (17%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*76G>T | 3'UTR (SNP) | VAF 24/189 reads (13%) | catalogued as rs1397530404, COSV100570405; called by muse, varscan2
